Somatic mutation profile of tumor specimen TCGA-99-8025-01A (aliquot TCGA-99-8025-01A-11D-2238-08) from TCGA case TCGA-99-8025, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 72.9 years (26,634 days).
Specimen TCGA-99-8025-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9bf3014-14d5-469f-a101-acf2f5e128ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-99-8025-10A (Blood Derived Normal), aliquot TCGA-99-8025-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1da8b3c-9372-482c-b448-6c4948f7bdfd

The open-access MAF lists 527 somatic variants for this specimen: 396 protein-altering or splice-affecting, 114 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 355, Silent 114, Nonsense Mutation 20, Frame Shift Del 7, Splice Site 7, RNA 6, Intron 5, 3'UTR 3, Frame Shift Ins 3, Nonstop Mutation 2, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFIH1 | c.2336G>A p.R779H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.689); catalogued as rs587777446, CM144545, COSV55124923, COSV55127542; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 19/33 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2219G>T p.G740V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59205460, COSV59217320; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- USH2A | c.4988-2A>G p.X1663_splice | Splice Site (SNP) | VAF 20/112 reads (18%) | catalogued as rs143521854; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV55963062; called by muse, mutect2, varscan2
- ABCC8 | c.2911G>C p.E971Q | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV56852133, COSV56857129; called by muse, mutect2, varscan2
- ADAM23 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV52218437; called by muse, mutect2, varscan2
- ADAMTS7 | c.3656A>C p.K1219T | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV66307802; called by muse, mutect2, varscan2
- ADCY1 | c.831G>T p.M277I | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV52036231; called by muse, mutect2, varscan2
- ADGRE2 | c.1065C>G p.F355L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV59694271, COSV59694412; called by muse, mutect2, varscan2
- ADGRL3 | c.1653C>A p.H551Q (on ENST00000506720 / NM_001322402.2; = p.H483Q on NM_015236.6) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV72230909; called by muse, mutect2, varscan2
- ADHFE1 | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52556106; called by muse, mutect2, varscan2
- ADNP | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV62425876; called by muse, mutect2, varscan2
- AFF2 | c.1421C>A p.P474H | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as COSV53993799; called by muse, varscan2
- AHCYL1 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63208896; called by muse, mutect2, varscan2
- AIRE | c.922C>G p.L308V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52394766; called by muse, mutect2, varscan2
- AKTIP | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV55815837; called by muse, mutect2, varscan2
- ALPK1 | c.2879C>T p.S960L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV51586405; called by muse, mutect2, varscan2
- ALX1 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.683); catalogued as COSV57492740; called by muse, mutect2
- AMIGO1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63990442; called by muse, mutect2, varscan2
- AMY2B | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 30/447 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100796290; called by muse, mutect2
- ANKRD30A | c.3516A>G p.I1172M (on ENST00000611781; = p.I1116M on NM_052997.2) | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs775871280, COSV64612906; called by muse, mutect2, varscan2
- ANKRD55 | c.891T>A p.N297K | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV61947515; called by muse, mutect2, varscan2
- AQP3 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53048517; called by muse, mutect2, varscan2
- ARHGAP32 | c.3901A>G p.R1301G (on ENST00000310343 / NM_001378025.1; = p.R952G on NM_014715.4) | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as rs369050135; called by muse, mutect2, varscan2
- ARHGEF10 | c.1994G>A p.R665Q (on ENST00000398564; = p.R640Q on NM_014629.4) | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs754235070, COSV50655285; called by muse, mutect2, varscan2
- ARID1A | c.1921-1G>A p.X641_splice | Splice Site (SNP) | VAF 20/87 reads (23%) | catalogued as COSV61380066; called by muse, mutect2, varscan2
- ARID1A | c.2223G>A p.M741I | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.885); catalogued as COSV61380074, COSV99055469; called by muse, mutect2, varscan2
- ARID1A | c.4499G>T p.G1500V | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV61380081; called by muse, mutect2, varscan2
- ARID1B | c.3881A>T p.Q1294L | Missense Mutation (SNP) | VAF 94/210 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.777); catalogued as COSV51666381; called by muse, mutect2, varscan2
- ARMC3 | c.2423G>T p.R808I | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV53062958; called by muse, mutect2, varscan2
- ARMC7 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.174); catalogued as COSV55461045; called by muse, mutect2, varscan2
- ASCC3 | c.3822T>A p.D1274E | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV61229918; called by muse, mutect2, varscan2
- ASIC2 | c.1384C>A p.L462I | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs1259540337, COSV56764356; called by muse, mutect2, varscan2
- ASTN1 | c.3205G>C p.D1069H | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62498773; called by muse, mutect2
- ATAD2 | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54882035; called by muse, mutect2, varscan2
- ATP13A5 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60870644; called by muse, mutect2, varscan2
- ATP9A | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1372076495, COSV58767959; called by muse, mutect2, varscan2
- ATPSCKMT | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV54727039, COSV99725786; called by muse, mutect2, varscan2
- BCAN | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.342); catalogued as COSV61257463; called by muse, mutect2, varscan2
- BEX1 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as COSV65580314; called by muse, mutect2, varscan2
- BMI1 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV64959203; called by muse, mutect2, varscan2
- BMP10 | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767015446, COSV54894476; called by muse, mutect2, varscan2
- BRD3 | c.1184A>G p.H395R | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV57704336; called by muse, mutect2, varscan2
- BRINP3 | c.1817A>T p.Q606L | Missense Mutation (SNP) | VAF 37/940 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV100818903, COSV66527387; called by muse, mutect2
- BTNL2 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs760675404, COSV66630953; called by muse, mutect2, varscan2
- BTRC | c.1762G>T p.A588S (on ENST00000370187 / NM_033637.4; = p.A552S on NM_003939.5) | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.003); catalogued as COSV64579804; called by muse, mutect2, varscan2
- C11orf87 | c.371C>A p.T124N | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV59357231; called by muse, mutect2, varscan2
- C11orf87 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1413462079, COSV59356112, COSV59357138; called by muse, mutect2, varscan2
- C3orf20 | c.1611G>C p.M537I | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV53786241; called by muse, mutect2, varscan2
- CAD | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53028096; called by muse, mutect2, varscan2
- CADM3 | c.554G>T p.G185V (on ENST00000368125 / NM_001127173.3; = p.G219V on NM_021189.5) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV63684427, COSV63685912; called by muse, mutect2
- CAMK2B | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.992); catalogued as COSV51661873; called by muse, mutect2, varscan2
- CAMLG | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs375153038, COSV99032530; called by muse, mutect2, varscan2
- CAST | c.452C>T p.S151L (on ENST00000341926; = p.S234L on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57786380; called by muse, mutect2, varscan2
- CBLN4 | c.188C>A p.S63* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as COSV50352028, COSV50353254; called by muse, mutect2, varscan2
- CCAR2 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV51515491; called by muse, mutect2, varscan2
- CCDC146 | c.1093A>T p.R365* | Nonsense Mutation (SNP) | VAF 36/168 reads (21%) | catalogued as COSV53550064; called by muse, mutect2, varscan2
- CCDC158 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as COSV66356329; called by muse, mutect2, varscan2
- CCDC74B | c.1098G>T p.R366S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100134441; called by muse, mutect2
- CDH11 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.56); catalogued as COSV51765723; called by muse, mutect2, varscan2
- CDH20 | c.1772C>A p.T591N | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53011804; called by muse, varscan2
- CDH23 | c.5527G>A p.D1843N | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM124355, COSV56470862; called by muse, mutect2, varscan2
- CEACAM6 | c.930G>T p.R310S | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as COSV52267887; called by muse, mutect2, varscan2
- CEL | c.793G>C p.E265Q (on ENST00000673714; = p.E262Q on NM_001807.6) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV60828035, COSV60829158; called by muse, mutect2, varscan2
- CENPF | c.5932G>T p.D1978Y | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100871677; called by muse, mutect2, varscan2
- CEP162 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV57620778; called by muse, mutect2, varscan2
- CEP85 | c.1179C>G p.F393L | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as COSV53330173; called by muse, mutect2
- CERCAM | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV65711194; called by muse, mutect2
- CFAP251 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV56611572; called by muse, mutect2, varscan2
- CHD5 | c.2690G>T p.R897M | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV52417207; called by muse, mutect2, varscan2
- CHD6 | c.1812G>C p.K604N | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58558417; called by muse, mutect2, varscan2
- CHD7 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 121/417 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV71112011; called by muse, mutect2, varscan2
- CHST12 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV51676076; called by muse, mutect2
- CILP | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs376150356; called by muse, mutect2, varscan2
- CLCA1 | c.451+1G>T p.X151_splice | Splice Site (SNP) | VAF 34/106 reads (32%) | catalogued as COSV52328577; called by muse, mutect2, varscan2
- CLCN1 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs202120426, COSV58370863; ClinVar: uncertain significance; called by muse, mutect2
- CLCN1 | c.2753G>C p.G918A | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.02); catalogued as COSV58368960, COSV58370870; called by muse, mutect2, varscan2
- CLIP2 | c.107C>G p.A36G | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV56280721; called by muse, mutect2, varscan2
- CLIP3 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs779092070, COSV53078453; called by muse, mutect2
- CLTC | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.614); catalogued as COSV52248865; called by muse, mutect2, varscan2
- CNGB1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as COSV51902220; called by muse, mutect2, varscan2
- CNKSR3 | c.535A>C p.K179Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV70481185; called by muse, mutect2, varscan2
- CNTLN | c.2453G>T p.R818L | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV52082611; called by muse, mutect2, varscan2
- CNTN2 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs1253351350, COSV59350782; called by muse, mutect2, varscan2
- CNTN3 | c.2408C>G p.T803R | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs1185245972, COSV55174625, COSV99726571; called by muse, mutect2, varscan2
- COL11A1 | c.2009G>T p.G670V | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62186481, COSV62189650; called by muse, mutect2, varscan2
- COL12A1 | c.4829T>C p.V1610A | Missense Mutation (SNP) | VAF 108/207 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV100485958; called by muse, mutect2, varscan2
- COL4A1 | c.3412C>T p.P1138S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as COSV65427363; called by muse, mutect2, varscan2
- COL4A3 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1482051609, COSV67416263; called by muse, mutect2, varscan2
- CR1 | c.5504G>T p.S1835I | Missense Mutation (SNP) | VAF 153/298 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV65459203; called by muse, mutect2, varscan2
- CSF2RB | c.2030C>A p.P677H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV53258556, COSV53260955; called by muse, mutect2, varscan2
- CSMD1 | c.2995A>G p.R999G (on ENST00000520002; = p.R998G on NM_033225.6) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs750697966, COSV59337493; called by muse, mutect2, varscan2
- CST11 | c.263A>T p.E88V | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65440853; called by muse, mutect2
- CUX1 | c.3538G>T p.E1180* | Nonsense Mutation (SNP) | VAF 18/134 reads (13%) | catalogued as COSV52903272; called by muse, mutect2, varscan2
- CYP4F11 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 103/177 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201684723, COSV56127805, COSV99930896; called by muse, mutect2, varscan2
- DHCR7 | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV62795666; called by muse, varscan2
- DMBT1 | c.7255C>T p.H2419Y (on ENST00000338354 / NM_001377530.1; = p.H1662Y on NM_004406.3) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV57547527, COSV57549855; called by muse, mutect2, varscan2
- DMD | c.7696G>C p.E2566Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.395); catalogued as COSV58919720; called by muse, mutect2, varscan2
- DNAJB2 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV60676497, COSV60676967; called by muse, mutect2, varscan2
- DNAJC10 | c.473G>T p.C158F | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51140069; called by muse, mutect2, varscan2
- DOCK3 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV56524866; called by muse, mutect2, varscan2
- DPM1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1384654859, COSV54866681; called by muse, mutect2, varscan2
- DPYD | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.965); catalogued as COSV64601413; called by muse, mutect2, varscan2
- DSP | c.4516A>G p.R1506G | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV65793402; called by muse, mutect2, varscan2
- DST | c.16246G>T p.A5416S (on ENST00000361203 / NM_001374722.1; = p.A3004S on NM_015548.5) | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as COSV55021306; called by muse, mutect2, varscan2
- EPC1 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs964692666, COSV53926887; called by muse, mutect2, varscan2
- EPHA3 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 14/135 reads (10%) | catalogued as COSV60698895, COSV60710849; called by muse, mutect2, varscan2
- ERN1 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV70502736; called by muse, mutect2
- ESPNL | c.2769A>C p.K923N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58035570; called by muse, mutect2, varscan2
- F5 | c.3422C>A p.T1141N | Missense Mutation (SNP) | VAF 125/385 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.383); catalogued as COSV63125176; called by muse, mutect2
- F8 | c.7020G>T p.M2340I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100371650; called by muse, mutect2, varscan2
- FAHD2B | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 20/127 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); catalogued as COSV55631347; called by muse, mutect2, varscan2
- FASLG | c.517G>C p.G173R | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60680287; called by muse, mutect2, varscan2
- FAT2 | c.5852C>A p.T1951N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV55821871; called by muse, mutect2, varscan2
- FDXACB1 | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200631446, COSV52789064; called by muse, mutect2, varscan2
- FFAR1 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as CM054758, COSV50055567; called by mutect2, varscan2
- FHDC1 | c.2572G>T p.D858Y | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52600679; called by muse, mutect2, varscan2
- FHL5 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as rs1331026642, COSV58735428, COSV58738259; called by muse, mutect2, varscan2
- FLG2 | c.5020C>A p.H1674N | Missense Mutation (SNP) | VAF 247/920 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV66169566; called by muse, mutect2, varscan2
- FLNC | c.5386G>C p.G1796R | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57957739; called by muse, mutect2, varscan2
- FMR1 | c.616A>T p.S206C | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as COSV54424232, COSV54425051; called by muse, mutect2, varscan2
- FNIP1 | c.1766A>G p.H589R | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs373270669; called by muse, mutect2, varscan2
- FOXP1 | c.2034A>T p.*678Cext*51 | Nonstop Mutation (SNP) | VAF 80/141 reads (57%) | catalogued as COSV59544655; called by muse, mutect2, varscan2
- FOXS1 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54066605; called by muse, mutect2, varscan2
- FRAS1 | c.1935C>G p.F645L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV53619391; called by muse, mutect2, varscan2
- FREM1 | c.3083C>A p.A1028E | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV66525225; called by muse, mutect2, varscan2
- FREM1 | c.248A>T p.H83L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV66525234; called by muse, mutect2
- FREM2 | c.7897G>A p.E2633K | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.665); catalogued as COSV54841242; called by muse, mutect2, varscan2
- GAA | c.1693C>T p.L565F | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV56409186; called by muse, mutect2, varscan2
- GAB1 | c.1891G>T p.D631Y | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53754072, COSV99528293; called by muse, mutect2, varscan2
- GAB1 | c.1892A>T p.D631V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99528295; called by muse, mutect2, varscan2
- GAD2 | c.317C>A p.P106H | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV52160385; called by muse, mutect2, varscan2
- GALNS | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV51938269; called by muse, mutect2, varscan2
- GALNT13 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs770420086, COSV67221532; called by muse, mutect2, varscan2
- GALNT13 | c.543G>C p.R181S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV67209831; called by muse, mutect2, varscan2
- GALNT14 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 51/135 reads (38%) | catalogued as COSV61106496; called by muse, mutect2, varscan2
- GALNTL5 | c.995G>C p.W332S | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV67180336; called by muse, mutect2, varscan2
- GATAD2B | c.1580G>T p.R527L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV64084564; called by muse, mutect2, varscan2
- GIGYF1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.021); catalogued as COSV51943257; called by muse, mutect2, varscan2
- GNAT3 | c.969G>T p.M323I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV68069061; called by muse, mutect2, varscan2
- GNG2 | c.81G>C p.R27S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1372857450, COSV58917043; called by muse, mutect2, varscan2
- GNL2 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66080802; called by muse, mutect2
- GNPTAB | c.920G>A p.S307N | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.201); catalogued as COSV73444125; called by muse, mutect2
- GPD2 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV60089756, COSV60093586; called by muse, mutect2, varscan2
- GPR35 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV60576361, COSV60577558; called by muse, mutect2
- GRK5 | c.1545G>A p.M515I | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV64866685; called by muse, mutect2, varscan2
- H4C4 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV61590892, COSV61591253, COSV61591576; called by muse, mutect2, varscan2
- H4C4 | c.90C>G p.I30M | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61591258; called by muse, mutect2, varscan2
- HDAC4 | c.1641G>C p.Q547H | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.227); catalogued as rs1283109120, COSV61867796; called by muse, mutect2
- HIPK1 | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61248619; called by muse, mutect2, varscan2
- HIPK1 | c.2341C>G p.P781A | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV61248629; called by muse, mutect2, varscan2
- HMX3 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV63501799; called by muse, mutect2, varscan2
- HTRA1 | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV64564471; called by muse, mutect2, varscan2
- ICE1 | c.5344G>C p.D1782H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56827121; called by muse, mutect2, varscan2
- IGF2R | c.5122G>T p.A1708S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV100807334; called by muse, mutect2
- IGSF9B | c.3098G>A p.G1033E | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); catalogued as COSV58069085; called by muse, mutect2, varscan2
- IL1RL1 | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.077); catalogued as COSV52117152; called by muse, mutect2, varscan2
- IL3 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320043317, COSV57309189; called by muse, mutect2, varscan2
- IL6 | c.282G>C p.K94N | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV51733066; called by muse, mutect2, varscan2
- ILDR2 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 98/377 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as COSV54832122; called by muse, mutect2, varscan2
- IMPG1 | c.1019T>C p.M340T | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs770754400, COSV64058869; called by muse, mutect2, varscan2
- INTS6L | c.2485A>T p.R829* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100878144, COSV66084726; called by muse, mutect2, varscan2
- ITGA4 | c.1954G>T p.G652W | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67897695; called by muse, mutect2, varscan2
- ITGAX | c.2990G>C p.R997P | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51646985; called by muse, mutect2, varscan2
- JAK1 | c.23A>G p.E8G | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV61092574; called by muse, mutect2
- JAKMIP1 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV51534267; called by muse, mutect2, varscan2
- KAT6B | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as COSV54749297; called by muse, mutect2, varscan2
- KATNA1 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59502869; called by muse, mutect2, varscan2
- KCNC2 | c.83C>A p.T28N | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.449); catalogued as COSV100128789; called by muse, mutect2, varscan2
- KCNJ1 | c.1003G>A p.G335R | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV60662049; called by muse, mutect2, varscan2
- KCNK10 | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV56646971; called by muse, mutect2, varscan2
- KIAA1109 | c.8902C>T p.P2968S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV52678018; called by muse, mutect2, varscan2
- KIAA1614 | c.3275G>A p.S1092N | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV62551107; called by muse, mutect2, varscan2
- KIAA1958 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61724707; called by muse, mutect2
- KIF17 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV56119278; called by muse, mutect2, varscan2
- KIF20B | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs947679379, COSV53309401; called by muse, mutect2, varscan2
- KIFC2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.006); catalogued as COSV56761524; called by muse, mutect2
- KIR3DL1 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.118); catalogued as COSV58492268; called by muse, mutect2, varscan2
- KIRREL1 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs376940730; called by muse, mutect2
- KLHL40 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs372246096; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLK15 | c.205A>G p.R69G | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.568); catalogued as COSV56827329; called by muse, mutect2, varscan2
- KLK7 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58344421; called by muse, mutect2
- KRT23 | c.718G>T p.V240F | Missense Mutation (SNP) | VAF 173/358 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV52928205; called by muse, mutect2, varscan2
- KRTAP11-1 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60094167; called by muse, mutect2, varscan2
- KRTAP24-1 | c.584C>A p.S195Y | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as COSV61088983, COSV61089648; called by muse, mutect2, varscan2
- KRTAP4-2 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 43/286 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs374053955, COSV66658662; called by muse, mutect2, varscan2
- LAMA5 | c.9282C>G p.I3094M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV53362406, COSV53368705; called by muse, mutect2
- LELP1 | c.71A>T p.E24V | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV64202516; called by muse, mutect2, varscan2
- LEMD3 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57651232; called by muse, mutect2, varscan2
- LGR4 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV64864728; called by muse, mutect2, varscan2
- LNPEP | c.1506C>G p.F502L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.151); catalogued as COSV51478659; called by muse, mutect2, varscan2
- LOXL2 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440188157, COSV66691974; called by muse, mutect2, varscan2
- LRP1B | c.13240G>T p.V4414L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV67234517; called by muse, mutect2, varscan2
- LRP1B | c.1007T>C p.I336T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs758969770, COSV67234520; called by muse, mutect2, varscan2
- LRRC30 | c.642C>A p.F214L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67301872; called by muse, mutect2, varscan2
- LRRC7 | c.1558C>A p.Q520K (on ENST00000651989 / NM_001370785.2; = p.Q487K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV50481669; called by muse, mutect2, varscan2
- LY6G5B | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 126/260 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV65507951; called by muse, mutect2, varscan2
- MAGEE1 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV63910636; called by muse, mutect2
- MAN2A1 | c.2308G>T p.D770Y | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs775656433, COSV54853433; called by muse, mutect2, varscan2
- MCHR2 | c.755T>C p.M252T | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.45); catalogued as rs913308823, COSV56004335; called by muse, mutect2, varscan2
- MED15 | c.1454C>T p.S485L (on ENST00000263205 / NM_001003891.3; = p.S445L on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53030231; called by muse, mutect2
- MFSD9 | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99302077; called by muse, mutect2, varscan2
- MICALL1 | c.1451G>C p.S484T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV53241242; called by muse, mutect2, varscan2
- MIER3 | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV61229681; called by muse, mutect2
- MKRN3 | c.130C>G p.P44A | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100091396, COSV58810358; called by muse, mutect2, varscan2
- MMP2 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54602347; called by muse, mutect2, varscan2
- MORN3 | c.497G>C p.R166T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.171); catalogued as COSV62507479; called by muse, mutect2, varscan2
- MROH7 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.143); catalogued as rs368337420; called by muse, mutect2, varscan2
- MSH4 | c.274G>C p.A92P | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.451); catalogued as COSV54204919; called by muse, mutect2, varscan2
- MUC17 | c.12536-2A>T p.X4179_splice | Splice Site (SNP) | VAF 82/250 reads (33%) | catalogued as COSV60292017; called by muse, mutect2, varscan2
- MUC5AC | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); catalogued as COSV62254302; called by muse, mutect2, varscan2
- MYCT1 | c.707G>T p.*236Lext*22 | Nonstop Mutation (SNP) | VAF 42/68 reads (62%) | catalogued as COSV65891478; called by muse, mutect2, varscan2
- MYO3A | c.4363C>G p.L1455V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV56335166; called by muse, mutect2, varscan2
- NALCN | c.4745G>C p.R1582P | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51954405, COSV99215015; called by muse, mutect2, varscan2
- NALCN | c.4744C>A p.R1582S | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV51959348, COSV99215021; called by muse, mutect2, varscan2
- NBPF3 | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as COSV59060171; called by muse, mutect2, varscan2
- NCOA3 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 28/129 reads (22%) | catalogued as COSV59069817; called by muse, mutect2, varscan2
- NCOA6 | c.2029A>C p.M677L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV62864845; called by mutect2, varscan2
- NDUFA7 | c.125C>G p.P42R | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56846846; called by muse, mutect2, varscan2
- NELFCD | c.278C>G p.S93C (on ENST00000602795; = p.S75C on NM_198976.4) | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV59746920; called by muse, mutect2, varscan2
- NFRKB | c.333C>A p.F111L (on ENST00000446488 / NM_001143835.2; = p.F124L on NM_006165.3) | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.97); catalogued as COSV58757779; called by muse, mutect2, varscan2
- NLRP14 | c.3170A>T p.E1057V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV55068231; called by muse, mutect2, varscan2
- NLRP6 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1282157045, COSV56460307; called by muse, mutect2, varscan2
- NOTCH4 | c.1687G>A p.G563S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV66681527; called by muse, mutect2, varscan2
- NPAS4 | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60651028, COSV60651549; called by muse, mutect2
- NPR3 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54088957; called by muse, mutect2, varscan2
- NR2F1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59068998; called by muse, mutect2, varscan2
- NT5C1B | c.937T>A p.S313T (on ENST00000359846 / NM_001199086.2; = p.S253T on NM_033253.4) | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58396616; called by muse, mutect2, varscan2
- NTNG2 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs918731538, COSV62367351; called by muse, mutect2, varscan2
- NUAK1 | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV54604344; called by muse, mutect2, varscan2
- NUBP2 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV99236509; called by muse, mutect2, varscan2
- NUF2 | c.949-2A>G p.X317_splice | Splice Site (SNP) | VAF 25/115 reads (22%) | catalogued as COSV54844368; called by muse, mutect2, varscan2
- OAS3 | c.3149A>T p.H1050L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV57446575; called by muse, mutect2, varscan2
- OGDH | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56052009; called by muse, mutect2, varscan2
- OGDHL | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.957); catalogued as COSV65103111; called by muse, mutect2, varscan2
- OR13G1 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62944478; called by muse, mutect2, varscan2
- OR1C1 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV68715848; called by muse, mutect2, varscan2
- OR1J4 | c.659A>C p.H220P | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV61589951; called by muse, mutect2, varscan2
- OR2A2 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 97/326 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV68871344, COSV68871799; called by muse, mutect2, varscan2
- OR2T4 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 139/300 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63544276; called by muse, mutect2, varscan2
- OR2T4 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 131/245 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100822664, COSV63544279; called by muse, mutect2, varscan2
- OR51A7 | c.848C>A p.P283Q | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376011053, COSV63788522; called by muse, mutect2, varscan2
- OR51B4 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV66517366; called by muse, mutect2, varscan2
- OR52E8 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs1225330423, COSV66206908; called by muse, mutect2, varscan2
- OR52M1 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV64171844, COSV64172186; called by muse, mutect2, varscan2
- OR5M3 | c.499T>C p.C167R | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV56565560, COSV56567230; called by muse, varscan2
- PABPC5 | c.1108C>A p.P370T | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57041380; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.14A>T p.E5V (on ENST00000374531 / NM_001037293.2; = p.E3V on NM_007203.5) | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57123167; called by muse, mutect2, varscan2
- PANK2 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57255085; called by muse, mutect2, varscan2
- PCDHA6 | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as COSV65353376; called by muse, mutect2, varscan2
- PCDHB2 | c.680C>A p.T227K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as COSV52030220, COSV52033669; called by muse, mutect2, varscan2
- PCDHGA3 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV53967732; called by muse, mutect2, varscan2
- PCDHGB5 | c.1916T>A p.L639Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53967747; called by muse, mutect2, varscan2
- PDE3A | c.1970G>T p.S657I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV62975228; called by muse, mutect2, varscan2
- PHF3 | c.866C>G p.S289* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV50312966, COSV50322278; called by muse, mutect2, varscan2
- PHIP | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 32/200 reads (16%) | catalogued as COSV51505941; called by muse, mutect2, varscan2
- PHLDB1 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 31/371 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV100616518; called by muse, mutect2
- PI4KA | c.2410C>G p.L804V | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55413836; called by muse, mutect2, varscan2
- PLCB3 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 83/508 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV54189449; called by muse, mutect2, varscan2
- PLEC | c.12397G>C p.V4133L (on ENST00000322810 / NM_201380.4; = p.V4023L on NM_000445.5) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV59649659; called by muse, mutect2, varscan2
- PLEKHB1 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as COSV57049710; called by muse, mutect2, varscan2
- PLK2 | c.734A>T p.N245I | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57107956; called by muse, mutect2, varscan2
- POM121L12 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV68693239; called by muse, mutect2, varscan2
- POU3F2 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV60409183; called by muse, mutect2, varscan2
- PPIH | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV59246199; called by muse, mutect2, varscan2
- PPP6R1 | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV69799965; called by muse, mutect2, varscan2
- PRKAA2 | c.1296A>G p.V432= | Splice Region (SNP) | VAF 25/64 reads (39%) | catalogued as COSV64804433; called by muse, mutect2, varscan2
- PRODH2 | c.1183G>A p.G395R (on ENST00000301175; = p.G319R on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1317656696, COSV56560318; called by muse, mutect2
- PRPF4B | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61784470; called by muse, mutect2, varscan2
- PRR23B | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as COSV100272065, COSV61494648; called by muse, mutect2, varscan2
- PRUNE2 | c.7081A>T p.I2361F | Missense Mutation (SNP) | VAF 120/230 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV65042865; called by muse, mutect2, varscan2
- PRUNE2 | c.2146T>C p.W716R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV65042867; called by muse, mutect2, varscan2
- PSG5 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 230/646 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs1289616448, COSV61654448; called by muse, mutect2, varscan2
- PSG8 | c.140A>C p.E47A | Missense Mutation (SNP) | VAF 138/437 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV60612748; called by muse, mutect2, varscan2
- PTCD3 | c.863A>C p.H288P | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV54480795; called by muse, mutect2, varscan2
- PTPRD | c.2621C>G p.S874C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV61956398; called by muse, mutect2, varscan2
- QRICH2 | c.1272G>C p.L424F | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); catalogued as rs767986772, COSV53154348; called by muse, mutect2
- RAB40B | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 116/227 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs149210378; called by muse, mutect2, varscan2
- RAG1 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV55025887; called by muse, varscan2
- RAG1 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.205); catalogued as COSV100200917, COSV55025896; called by muse, varscan2
- RASAL1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.482); catalogued as COSV55656980, COSV99922174; called by muse, mutect2, varscan2
- RASSF6 | c.116A>G p.Q39R (on ENST00000342081 / NM_201431.2; = p.Q7R on NM_177532.5) | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV56718964; called by muse, mutect2, varscan2
- RB1 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as rs145729675, COSV99924682; called by muse, mutect2
- RFX4 | c.2178C>G p.N726K (on ENST00000392842 / NM_213594.3; = p.N632K on NM_032491.6) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV57576875, COSV57581572; called by muse, mutect2, varscan2
- RHD | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.491); catalogued as COSV59646494; called by muse, mutect2, varscan2
- RNASE10 | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60517887; called by muse, mutect2, varscan2
- RNASEL | c.1198C>A p.R400S | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.293); catalogued as COSV62377165; called by muse, mutect2, varscan2
- RRNAD1 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as COSV63929157; called by muse, mutect2, varscan2
- RXFP3 | c.1214G>T p.W405L | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV57506304; called by muse, mutect2, varscan2
- RYR1 | c.12177G>T p.K4059N | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62100652; called by muse, mutect2, varscan2
- RYR2 | c.8441C>T p.S2814F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV63691667; called by muse, mutect2, varscan2
- SAMD9 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV66076111; called by muse, mutect2, varscan2
- SASS6 | c.172T>C p.Y58H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54928440, COSV54929875; called by muse, mutect2, varscan2
- SCN10A | c.2363G>A p.G788E | Missense Mutation (SNP) | VAF 78/126 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV71861807; called by muse, mutect2, varscan2
- SCN4A | c.49T>A p.L17M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV71127361; called by muse, mutect2
- SCN5A | c.5173C>A p.P1725T (on ENST00000333535 / NM_198056.3; = p.P1724T on NM_000335.5) | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61128167; called by muse, mutect2, varscan2
- SCN7A | c.4530G>T p.L1510F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69272484; called by muse, mutect2, varscan2
- SEC14L5 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs1326679378, COSV52039232; called by muse, mutect2, varscan2
- SEMA4C | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV59691212; called by muse, mutect2, varscan2
- SETBP1 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); catalogued as COSV56325898; called by muse, mutect2, varscan2
- SETD1A | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as COSV52688990; called by muse, mutect2, varscan2
- SLC15A2 | c.737C>G p.P246R | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV55198482, COSV55200380; called by muse, mutect2, varscan2
- SLC27A6 | c.1235G>T p.W412L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV52484168; called by muse, mutect2, varscan2
- SLC31A2 | c.23C>G p.S8* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV52272790; called by muse, mutect2
- SLC44A1 | c.1253G>T p.R418M | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58265259; called by muse, mutect2, varscan2
- SLC7A6 | c.1222C>G p.Q408E | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV50450195; called by muse, mutect2, varscan2
- SMARCD2 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV56740064; called by muse, mutect2
- SMOC1 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776638586, CM116129, COSV62759511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA18 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV54645951; called by muse, mutect2, varscan2
- SPEG | c.5900C>A p.A1967D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV56671572; called by muse, mutect2
- SRP54 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV53740339; called by muse, mutect2, varscan2
- SRPK1 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs1389050362, COSV100644341; called by muse, mutect2
- SRRT | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1371938437, COSV53815940, COSV99574056; called by muse, mutect2, varscan2
- ST14 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs368423798; called by mutect2, varscan2
- ST6GAL2 | c.1586C>A p.S529Y | Missense Mutation (SNP) | VAF 30/181 reads (17%) | PolyPhen possibly damaging (0.525); catalogued as COSV62417072; called by muse, mutect2, varscan2
- STAR | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as COSV52417722; called by muse, mutect2, varscan2
- STEAP2 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | catalogued as COSV55291717; called by muse, mutect2, varscan2
- STON2 | c.1339A>G p.I447V (on ENST00000649389 / NM_001366849.2; = p.I390V on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as rs770533076, COSV50846441; called by muse, mutect2, varscan2
- SUN1 | c.1037G>A p.R346Q (on ENST00000405266 / NM_001367651.1; = p.R226Q on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.434); catalogued as COSV61778548; called by muse, mutect2, varscan2
- SVIL | c.3707T>G p.I1236S (on ENST00000355867 / NM_021738.3; = p.I810S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63444409; called by muse, mutect2, varscan2
- SYNE2 | c.10022C>G p.S3341* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV59939320; called by muse, mutect2, varscan2
- TAF1C | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV58987199; called by muse, mutect2, varscan2
- TANK | c.83A>C p.K28T | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV99376115; called by muse, mutect2, varscan2
- TBXAS1 | c.1264G>C p.G422R | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54947321; called by muse, mutect2, varscan2
- TCHHL1 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 87/404 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as COSV64285924, COSV64286176; called by muse, mutect2, varscan2
- TENM1 | c.978C>G p.I326M | Missense Mutation (SNP) | VAF 118/235 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV64434651, COSV64442729; called by muse, mutect2, varscan2
- TGFBR3 | c.1414-2A>T p.X472_splice | Splice Site (SNP) | VAF 19/158 reads (12%) | catalogued as COSV53026843; called by muse, mutect2
- THOC2 | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55548663; called by muse, mutect2, varscan2
- THSD7A | c.2936T>G p.V979G | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV70266557; called by muse, mutect2, varscan2
- THSD7B | c.2420C>A p.P807H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.754); catalogued as COSV55693156; called by muse, mutect2, varscan2
- TJP2 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 49/285 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1407663473, COSV55268784; called by muse, mutect2, varscan2
- TLL1 | c.1841G>T p.C614F | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99287228; called by muse, mutect2, varscan2
- TLR1 | c.1547T>A p.M516K | Missense Mutation (SNP) | VAF 119/391 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs55812771, COSV58304716; ClinVar: benign; called by muse, mutect2, varscan2
- TMEM176B | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.136); catalogued as rs1336047907, COSV58440055; called by muse, mutect2, varscan2
- TMPRSS11E | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV59519603; called by muse, mutect2, varscan2
- TNNT3 | c.574G>C p.E192Q (on ENST00000397301 / NM_001367846.1; = p.E181Q on NM_006757.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV53487404; called by muse, mutect2
- TRIOBP | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs891768566, COSV60379451; called by muse, mutect2, varscan2
- TSC1 | c.1224C>A p.H408Q | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.48); catalogued as COSV53768258; called by muse, mutect2, varscan2
- TTC29 | c.52G>C p.A18P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.855); catalogued as COSV57277203; called by muse, mutect2, varscan2
- UBE3A | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51666916; called by muse, mutect2, varscan2
- UBE4A | c.1576C>A p.H526N (on ENST00000252108 / NM_001204077.2; = p.H533N on NM_004788.4) | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.756); catalogued as COSV52804785; called by muse, mutect2, varscan2
- USH2A | c.11389+1G>T p.X3797_splice | Splice Site (SNP) | VAF 62/134 reads (46%) | catalogued as rs368770647, CS153007, COSV56385581; called by muse, mutect2, varscan2
- USH2A | c.7525C>T p.R2509W | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1394948601, COSV56357291, COSV56362607; called by muse, mutect2, varscan2
- USP8 | c.1913G>A p.R638K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.728); catalogued as COSV100208863, COSV56165116; called by muse, mutect2, varscan2
- VAV3 | c.2478G>T p.W826C | Missense Mutation (SNP) | VAF 105/322 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58384745; called by muse, mutect2, varscan2
- VILL | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52185378; called by muse, mutect2, varscan2
- WDR12 | c.1205G>T p.S402I | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53687553; called by muse, mutect2, varscan2
- XIRP1 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 141/377 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV61139123; called by muse, mutect2, varscan2
- XIRP2 | c.242C>T p.A81V (on ENST00000628543; = p.A256V on NM_152381.6) | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54708943; called by muse, mutect2, varscan2
- XKR7 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as COSV73813236, COSV73813381; called by muse, mutect2, varscan2
- XPC | c.2224C>G p.Q742E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV53205321; called by muse, mutect2, varscan2
- XPR1 | c.2058G>T p.L686F | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.649); catalogued as COSV62557595; called by muse, mutect2, varscan2
- XYLT1 | c.2542C>T p.Q848* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV54487134; called by muse, mutect2, varscan2
- ZBTB39 | c.2124G>C p.K708N | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.724); catalogued as COSV55629675; called by muse, mutect2, varscan2
- ZCCHC2 | c.1902G>C p.E634D | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV54038749; called by muse, mutect2, varscan2
- ZFPM2 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV65874234; called by muse, mutect2, varscan2
- ZGRF1 | c.3657A>T p.Q1219H | Missense Mutation (SNP) | VAF 98/266 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV58407939, COSV58409389; called by muse, mutect2, varscan2
- ZMAT4 | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.996); catalogued as COSV52702652, COSV99909491; called by muse, mutect2, varscan2
- ZMPSTE24 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs373684692, COSV65639406, COSV65640266; called by muse, mutect2, varscan2
- ZNF184 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV53004536; called by muse, mutect2, varscan2
- ZNF208 | c.3265G>C p.E1089Q | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV68103234, COSV68107984; called by muse, mutect2, varscan2
- ZNF224 | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61242513; called by muse, mutect2, varscan2
- ZNF234 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as COSV70603798; called by muse, mutect2, varscan2
- ZNF234 | c.1174G>T p.G392* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV101468363; called by muse, mutect2, varscan2
- ZNF248 | c.375G>T p.L125F | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.39); catalogued as rs780991259, COSV61997914; called by muse, mutect2, varscan2
- ZNF254 | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 89/332 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60054527; called by muse, mutect2, varscan2
- ZNF275 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV100936238; called by muse, mutect2
- ZNF280A | c.556G>T p.G186* | Nonsense Mutation (SNP) | VAF 15/142 reads (11%) | catalogued as COSV57480968; called by muse, mutect2, varscan2
- ZNF423 | c.419G>A p.G140E (on ENST00000563137 / NM_001379286.1; = p.G132E on NM_015069.4) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52193357; called by muse, mutect2
- ZNF443 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.792); catalogued as rs374780459; called by muse, mutect2
- ZNF536 | c.3709G>T p.G1237C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.299); catalogued as COSV62826300; called by muse, mutect2, varscan2
- ZNF577 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs374411694; called by muse, mutect2, varscan2
- ZNF595 | c.1598A>T p.Q533L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV59550915; called by muse, mutect2, varscan2
- ZNF782 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56653238; called by muse, mutect2
- ZNRF3 | c.2239G>C p.G747R (on ENST00000544604 / NM_001206998.2; = p.G647R on NM_032173.3) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.277); catalogued as COSV60435433; called by muse, mutect2, varscan2
- ZP4 | c.1239C>A p.H413Q | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63912400; called by muse, mutect2, varscan2
- ASIC4 | c.1107del p.I370Sfs*28 (on ENST00000347842 / NM_182847.3; = p.I389Sfs*28 on NM_018674.6) | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- FANCD2 | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2
- FCGBP | c.9346G>T p.D3116Y | Missense Mutation (SNP) | VAF 84/782 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.081); called by muse, mutect2
- FCGBP | c.5743G>T p.D1915Y | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- HDAC4 | c.3082_3101del p.W1028Nfs*41 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- IGKV1-27 | c.150delinsAA p.I51Nfs*2 | Frame Shift Ins (INS) | VAF 53/373 reads (14%) | called by pindel, varscan2*
- IGKV1-27 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, varscan2
- ITGA3 | c.702_703insGA p.S235Dfs*23 | Frame Shift Ins (INS) | VAF 68/419 reads (16%) | called by mutect2, pindel, varscan2
- MYH1 | c.3831del p.T1278Qfs*18 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- NEUROD4 | c.212del p.G71Vfs*7 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by pindel, varscan2*
- OR10H2 | c.388del p.L130Cfs*7 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- OTUD3 | c.463del p.N156Mfs*15 | Frame Shift Del (DEL) | VAF 8/98 reads (8%) | called by mutect2, pindel
- PDE4DIP | c.2617C>T p.L873F | Missense Mutation (SNP) | VAF 55/519 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV3-1 | c.102G>T p.M34I | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTLL6 | c.2116del p.A706Lfs*2 (on ENST00000393382 / NM_001130918.3; = p.A399Lfs*2 on NM_173623.3) | Frame Shift Del (DEL) | VAF 55/130 reads (42%) | called by mutect2, pindel, varscan2
- VPS18 | c.1069dup p.D357Gfs*27 | Frame Shift Ins (INS) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- VPS72 | c.887A>G p.H296R | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT tolerated (0.91); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF84 | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 62/103 reads (60%) | called by muse, mutect2, varscan2
- AASDH | c.3177T>C p.S1059= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV52707491; called by muse, mutect2, varscan2
- ADAM19 | c.2307G>A p.T769= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs763134049, COSV57422622, COSV57428023; called by mutect2, varscan2
- AHR | c.2307G>T p.V769= | Silent (SNP) | VAF 47/239 reads (20%) | catalogued as COSV54124248; called by muse, mutect2, varscan2
- AKAP8 | c.570G>C p.R190= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV54103092; called by muse, mutect2, varscan2
- ALDH6A1 | c.1413G>C p.V471= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs1271912078, COSV63245751; called by muse, mutect2
- ARHGAP21 | c.3087A>T p.L1029= | Silent (SNP) | VAF 94/208 reads (45%) | catalogued as COSV57606977; called by muse, mutect2, varscan2
- ARHGAP22 | c.18C>T p.I6= | Silent (SNP) | VAF 11/152 reads (7%) | catalogued as COSV50949045; called by muse, mutect2
- BMP8A | c.900C>G p.V300= | Silent (SNP) | VAF 18/183 reads (10%) | catalogued as rs1395970313, COSV59033171; called by muse, varscan2
- CCDC185 | c.633G>A p.K211= | Silent (SNP) | VAF 51/294 reads (17%) | catalogued as COSV64821133; called by muse, mutect2, varscan2
- CCDC27 | c.180C>T p.S60= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as COSV53901027; called by muse, mutect2, varscan2
- CD8A | c.60G>A p.R20= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs752636744, COSV52157990; called by muse, mutect2
- CENPF | c.5931G>T p.L1977= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV65279190; called by muse, mutect2, varscan2
- CFAP65 | c.2082C>T p.C694= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV58562356; called by muse, mutect2, varscan2
- CHRM1 | c.1089G>T p.A363= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV61007009; called by muse, mutect2, varscan2
- CNTN5 | c.2241A>T p.R747= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV54320309; called by muse, mutect2, varscan2
- CNTNAP4 | c.2241C>A p.T747= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs748587038, COSV56685789; called by muse, mutect2, varscan2
- COL14A1 | c.2067T>C p.Y689= | Silent (SNP) | VAF 71/158 reads (45%) | catalogued as rs375264245; called by muse, mutect2, varscan2
- CSMD1 | c.6174G>T p.T2058= (on ENST00000520002; = p.T2057= on NM_033225.6) | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as rs765416134, COSV59281908, COSV59337468; called by muse, mutect2, varscan2
- CT55 | c.87C>T p.L29= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs1465830914, COSV52278068; called by muse, mutect2, varscan2
- DAB2 | c.240G>T p.A80= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as COSV57915576; called by muse, mutect2, varscan2
- DHX38 | c.420G>T p.R140= | Silent (SNP) | VAF 47/199 reads (24%) | catalogued as COSV51698686; called by muse, mutect2, varscan2
- DIAPH3 | c.366C>T p.L122= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV57369723; called by muse, mutect2, varscan2
- DOP1B | c.3960G>C p.L1320= | Silent (SNP) | VAF 66/245 reads (27%) | catalogued as COSV67693819; called by muse, mutect2, varscan2
- DUSP10 | c.891G>T p.G297= | Silent (SNP) | VAF 82/150 reads (55%) | catalogued as COSV60458271; called by muse, mutect2, varscan2
- ENAH | c.1359C>T p.A453= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as COSV52869168; called by muse, mutect2, varscan2
- FAT1 | c.12042G>C p.T4014= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV71672082, COSV71674690; called by muse, mutect2, varscan2
- FER1L6 | c.957G>A p.R319= | Silent (SNP) | VAF 62/206 reads (30%) | catalogued as COSV67550731; called by muse, mutect2, varscan2
- FGFR1 | c.78C>A p.T26= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV58336839; called by muse, mutect2, varscan2
- FLNC | c.756C>A p.T252= | Silent (SNP) | VAF 33/252 reads (13%) | catalogued as COSV57957731; called by muse, mutect2, varscan2
- FMOD | c.706C>A p.R236= | Silent (SNP) | VAF 80/287 reads (28%) | catalogued as COSV61610193; called by muse, mutect2, varscan2
- FREM2 | c.2499C>T p.L833= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs550946518, COSV54841233; called by muse, mutect2, varscan2
- FUT8 | c.1506G>A p.Q502= (on ENST00000360689 / NM_001371534.1; = p.Q339= on NM_004480.4) | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as rs368942174, COSV100651212, COSV61292734; called by muse, mutect2, varscan2
- GDAP1 | c.82C>T p.L28= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs1328547487, COSV55184898, COSV55186048, COSV55186438; called by muse, mutect2, varscan2
- GPR161 | c.258G>A p.T86= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as rs990607394, COSV54791543; called by muse, mutect2
- GPR55 | c.915C>T p.S305= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV67407980; called by muse, mutect2, varscan2
- GRID1 | c.1104C>A p.T368= | Silent (SNP) | VAF 67/164 reads (41%) | catalogued as COSV60034459; called by muse, mutect2, varscan2
- GSTO2 | c.531C>T p.L177= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV58538715; called by muse, mutect2, varscan2
- HERC2 | c.5667A>T p.P1889= | Silent (SNP) | VAF 43/201 reads (21%) | catalogued as COSV55328928; called by muse, mutect2, varscan2
- HHIPL1 | c.573C>T p.N191= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs746149102, COSV58091401; called by muse, mutect2, varscan2
- HIPK2 | c.2097A>T p.P699= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV61228928; called by muse, mutect2, varscan2
- HK2 | c.2487G>T p.R829= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV51876225; called by muse, mutect2, varscan2
- HP1BP3 | c.1416G>C p.V472= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as COSV56563173; called by muse, mutect2, varscan2
- HSD3B1 | c.504G>A p.A168= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as rs754741963, COSV52491132; called by muse, mutect2, varscan2
- IGSF9B | c.651T>A p.A217= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV58069099; called by muse, mutect2, varscan2
- JAG1 | c.891C>T p.L297= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV54758301; called by muse, mutect2
- KALRN | c.5289C>A p.S1763= (on ENST00000360013 / NM_001024660.4; = p.S66= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99361943; called by muse, mutect2
- KCNA6 | c.138T>C p.N46= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV54975976; called by muse, mutect2, varscan2
- KCNC2 | c.84C>A p.T28= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV100128785; called by muse, mutect2, varscan2
- KCNJ16 | c.1053C>A p.L351= | Silent (SNP) | VAF 69/158 reads (44%) | catalogued as rs986208220, COSV52254418; called by muse, mutect2, varscan2
- KIF13B | c.3594G>T p.A1198= | Silent (SNP) | VAF 89/167 reads (53%) | catalogued as COSV72954461, COSV72954539; called by muse, mutect2, varscan2
- L1CAM | c.531G>A p.L177= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as rs1557092915, COSV62828587; called by muse, mutect2, varscan2
- LILRA4 | c.828C>T p.S276= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV52491876, COSV52492763; called by muse, mutect2, varscan2
- LIMK2 | c.1239G>A p.L413= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV59182965; called by muse, mutect2, varscan2
- MAP11 | c.1656C>G p.L552= | Silent (SNP) | VAF 34/195 reads (17%) | catalogued as rs1161533751, COSV57586765; called by muse, mutect2, varscan2
- MFSD9 | c.1188G>T p.T396= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV51495017; called by muse, mutect2, varscan2
- MGAM | c.276G>A p.V92= | Silent (SNP) | VAF 42/152 reads (28%) | catalogued as COSV71885609; called by muse, varscan2
- MICAL3 | c.4344G>A p.S1448= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs761910346, COSV71588611; called by muse, mutect2, varscan2
- MINAR1 | c.1251A>G p.P417= | Silent (SNP) | VAF 66/106 reads (62%) | catalogued as rs773717135, COSV59583806; called by muse, mutect2, varscan2
- MROH1 | c.786G>A p.Q262= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV58190390; called by muse, mutect2, varscan2
- NAP1L4 | c.675C>T p.Y225= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV65881343; called by muse, mutect2, varscan2
- NLRP3 | c.2088C>A p.G696= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as COSV60222005; called by muse, mutect2, varscan2
- NLRP8 | c.2724G>A p.L908= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as COSV52589175; called by muse, mutect2, varscan2
- NOS2 | c.1824G>T p.S608= | Silent (SNP) | VAF 78/153 reads (51%) | catalogued as COSV100569464, COSV58224650; called by muse, mutect2, varscan2
- NRDC | c.1017C>T p.R339= | Silent (SNP) | VAF 43/212 reads (20%) | catalogued as COSV61405466; called by muse, mutect2, varscan2
- NUBP2 | c.33C>T p.A11= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs146719191; called by muse, mutect2, varscan2
- NXPH3 | c.351C>T p.L117= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs1317378867, COSV60872344; called by muse, mutect2, varscan2
- OR10G7 | c.594C>A p.I198= | Silent (SNP) | VAF 74/400 reads (19%) | catalogued as COSV57867512; called by muse, mutect2, varscan2
- OR11H1 | c.102C>A p.L34= | Silent (SNP) | VAF 100/445 reads (22%) | catalogued as COSV53272060, COSV53272581; called by muse, mutect2, varscan2
- OR6K2 | c.96C>G p.L32= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV62743631; called by muse, mutect2, varscan2
- OR6K3 | c.711C>A p.V237= (on ENST00000368146; = p.V221= on NM_001005327.2) | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as COSV63745529; called by muse, mutect2, varscan2
- PAPPA | c.3522G>C p.S1174= | Silent (SNP) | VAF 101/218 reads (46%) | catalogued as COSV60285761; called by muse, mutect2, varscan2
- PAPPA2 | c.1647G>T p.L549= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as COSV62780069; called by muse, mutect2, varscan2
- PCDH15 | c.1794C>T p.I598= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV57303833, COSV57330842; called by muse, mutect2, varscan2
- PCK1 | c.642G>A p.P214= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs138176491; called by muse, mutect2, varscan2
- PCSK2 | c.171C>T p.V57= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV52735263; called by muse, mutect2, varscan2
- PGGHG | c.1803G>T p.G601= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs374350776, COSV66888253; called by muse, mutect2, varscan2
- PIK3CG | c.2133G>A p.Q711= | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as COSV63249504; called by muse, mutect2, varscan2
- PKHD1 | c.2022C>T p.L674= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV61881372; called by muse, mutect2, varscan2
- PLXNA4 | c.1926C>T p.T642= | Silent (SNP) | VAF 41/322 reads (13%) | catalogued as rs759080529, COSV58134585; called by muse, mutect2, varscan2
- PREB | c.801G>C p.V267= | Silent (SNP) | VAF 24/154 reads (16%) | catalogued as COSV53206618; called by muse, mutect2, varscan2
- PSPC1 | c.612A>G p.A204= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV58888784; called by muse, mutect2, varscan2
- PXDN | c.2673G>A p.S891= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs777543085, COSV53237402; called by muse, mutect2, varscan2
- RELN | c.3894A>T p.G1298= | Silent (SNP) | VAF 93/275 reads (34%) | catalogued as COSV59009643; called by muse, mutect2, varscan2
- RIN3 | c.315G>A p.L105= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as COSV53650458; called by muse, mutect2, varscan2
- RYR1 | c.10317C>T p.G3439= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs1174927393, COSV62100646; called by mutect2, varscan2
- SCN1A | c.2451G>A p.L817= (on ENST00000303395 / NM_001202435.3; = p.L806= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100319988, COSV57672760, COSV57674026; called by muse, mutect2, varscan2
- SCN3B | c.394C>A p.R132= | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as COSV54799755; called by muse, mutect2, varscan2
- SETBP1 | c.1233G>A p.L411= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as COSV99953195; called by muse, mutect2, varscan2
- SLC44A4 | c.51C>G p.V17= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV57667699; called by muse, mutect2, varscan2
- SLC7A4 | c.177A>T p.T59= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV60384453; called by muse, mutect2, varscan2
- SMUG1 | c.159C>T p.I53= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs768901193, COSV54539783; called by muse, mutect2, varscan2
- SNTG2 | c.810G>T p.R270= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV57988866; called by muse, mutect2, varscan2
- ST14 | c.939C>G p.L313= | Silent (SNP) | VAF 54/330 reads (16%) | catalogued as COSV53834104; called by muse, varscan2
- STMN4 | c.381C>A p.I127= (on ENST00000265770 / NM_001283054.2; = p.I154= on NM_030795.4) | Silent (SNP) | VAF 57/94 reads (61%) | catalogued as COSV56109324; called by muse, mutect2, varscan2
- SUCNR1 | c.387A>T p.R129= | Silent (SNP) | VAF 85/145 reads (59%) | catalogued as COSV62912377; called by muse, mutect2, varscan2
- SYCP2L | c.402G>A p.S134= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs577284810, COSV51654156; called by muse, mutect2, varscan2
- SYNE2 | c.3855A>T p.V1285= | Silent (SNP) | VAF 51/112 reads (46%) | catalogued as rs371327530; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAF1L | c.3894C>T p.C1298= | Silent (SNP) | VAF 140/321 reads (44%) | catalogued as rs756616614, COSV54263603; called by muse, mutect2, varscan2
- TBC1D9B | c.1281G>T p.S427= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV62282332, COSV62283387; called by muse, mutect2, varscan2
- TMPRSS13 | c.1149G>T p.A383= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV70626552; called by muse, mutect2, varscan2
- TRIML1 | c.1071C>A p.I357= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV60194111, COSV60194804; called by muse, mutect2, varscan2
- TRPM6 | c.5460G>A p.E1820= | Silent (SNP) | VAF 27/328 reads (8%) | catalogued as COSV62513799; called by muse, mutect2
- UBB | c.159C>A p.G53= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as COSV100141632; called by muse, mutect2, varscan2
- USH1C | c.1269G>A p.E423= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV50020668; called by muse, mutect2, varscan2
- USP2 | c.900C>T p.Y300= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as rs765060665, COSV52730157; called by muse, mutect2, varscan2
- WDR72 | c.2175G>C p.L725= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV64748704; called by muse, mutect2, varscan2
- XYLB | c.477C>T p.L159= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV52913976, COSV52915227; called by muse, mutect2, varscan2
- ZC2HC1C | c.150G>A p.R50= | Silent (SNP) | VAF 86/166 reads (52%) | catalogued as COSV53172705; called by muse, mutect2, varscan2
- ZNF222 | c.684T>A p.P228= | Silent (SNP) | VAF 39/351 reads (11%) | catalogued as COSV51827102; called by muse, mutect2, varscan2
- ZNF521 | c.2394G>A p.L798= | Silent (SNP) | VAF 29/193 reads (15%) | catalogued as COSV64128177; called by muse, mutect2, varscan2
- ZNF618 | c.2838C>T p.L946= (on ENST00000374126 / NM_001318042.2; = p.L853= on NM_133374.2) | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as rs1564354032, COSV55923236; called by muse, mutect2, varscan2
- ZNF684 | c.471C>T p.N157= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs527509736, COSV65518868; called by muse, mutect2, varscan2
- ZNF793 | c.222G>T p.P74= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV71325061; called by muse, mutect2, varscan2
- ZP4 | c.1560C>A p.A520= | Silent (SNP) | VAF 97/175 reads (55%) | catalogued as COSV63912394; called by muse, mutect2, varscan2
- ANK3 | c.*2A>G | 3'UTR (SNP) | VAF 19/182 reads (10%) | catalogued as COSV99779840; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500355 T>C | 5'Flank (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- C16orf82 | c.-164G>T | 5'UTR (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- DCHS2 | n.3758G>T | RNA (SNP) | VAF 18/48 reads (38%) | catalogued as COSV61767825, COSV61773763; called by muse, mutect2, varscan2
- FGF13 | c.403-32067C>A | Intron (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100264122; called by muse, mutect2, varscan2
- FN1 | c.3797-1230C>T | Intron (SNP) | VAF 19/81 reads (23%) | catalogued as COSV60555531; called by muse, mutect2, varscan2
- FOLH1B | n.922A>T | RNA (SNP) | VAF 35/201 reads (17%) | called by muse, mutect2, varscan2
- LKAAEAR1 | c.*9G>C | 3'UTR (SNP) | VAF 15/78 reads (19%) | catalogued as COSV57478452, COSV57478731; called by muse, mutect2, varscan2
- NBPF7 | n.352G>C | RNA (SNP) | VAF 59/359 reads (16%) | catalogued as rs1295407485; called by muse, mutect2, varscan2
- NRXN1 | c.772+1099G>T | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs1181781149, COSV68020353; called by muse, mutect2, varscan2
- OGFOD3 | c.824-1933G>A | Intron (SNP) | VAF 49/199 reads (25%) | catalogued as rs758959243, COSV57344210; called by muse, mutect2, varscan2
- OR2U1P | n.878A>T | RNA (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- TMEM132E | chr17:34579083 G>T | 5'Flank (SNP) | VAF 72/145 reads (50%) | called by muse, mutect2, varscan2
- TSPYL6 | c.*2C>T | 3'UTR (SNP) | VAF 27/104 reads (26%) | catalogued as COSV100336331, COSV100336576; called by muse, mutect2, varscan2
- TTN | c.34265-2994del | Intron (DEL) | VAF 30/295 reads (10%) | called by mutect2, pindel, varscan2
- XIST | n.8031G>T | RNA (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- ZNF271P | n.1770C>G | RNA (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
